Somatic mutation profile of tumor specimen TCGA-AP-A0LF-01A (aliquot TCGA-AP-A0LF-01A-11D-A122-09) from TCGA case TCGA-AP-A0LF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AP-A0LF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be01f3b0-c1ed-463f-9ae2-be42ad7f0199.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LF-10A (Blood Derived Normal), aliquot TCGA-AP-A0LF-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2370aa5a-3500-4a77-943d-c7526f285dc8

The open-access MAF lists 252 somatic variants for this specimen: 206 protein-altering or splice-affecting, 46 silent.
By variant classification: Missense Mutation 184, Silent 46, Nonsense Mutation 11, Splice Site 5, Splice Region 4, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 174/289 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.1019A>T p.N340I | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.784); catalogued as COSV70041001; called by muse, mutect2, varscan2
- ABCA13 | c.12586G>A p.A4196T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV68949879; called by muse, mutect2, varscan2
- ACTRT2 | c.1111G>A p.V371M | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs757742785, COSV65760155; called by muse, mutect2, varscan2
- ADGRA2 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs374752785, COSV59446455; called by muse, mutect2, varscan2
- ADGRG3 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs146307657, COSV59650526; called by muse, mutect2, varscan2
- ADGRV1 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.634); catalogued as COSV67984717, COSV67992872; called by muse, mutect2, varscan2
- ADNP | c.3187G>C p.E1063Q | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV62426528; called by muse, mutect2, varscan2
- AFMID | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs199514072, COSV59977218; called by muse, mutect2, varscan2
- ALB | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV55741266; called by muse, mutect2, varscan2
- AMBRA1 | c.2892G>C p.R964S (on ENST00000458649 / NM_001367468.1; = p.R874S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV54060476; called by muse, mutect2, varscan2
- AMHR2 | c.870C>G p.Y290* | Nonsense Mutation (SNP) | VAF 16/154 reads (10%) | catalogued as COSV57686651; called by muse, mutect2, varscan2
- AMPH | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57752548; called by muse, mutect2, varscan2
- ANKRD42 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 107/266 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52617605; called by muse, mutect2, varscan2
- ARMC6 | c.463C>A p.L155M (on ENST00000392336; = p.L130M on NM_033415.4) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV54183553; called by muse, mutect2, varscan2
- ASMT | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV67110265; called by muse, mutect2, varscan2
- BCL2L11 | c.251G>C p.R84T | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV58029487, COSV58031724; called by muse, mutect2, varscan2
- BCL9L | c.2840C>T p.S947L | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139195814; called by muse, mutect2, varscan2
- BMPR1A | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV100923448, COSV64408049; called by muse, mutect2, varscan2
- BTAF1 | c.4093G>A p.E1365K | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV56437949; called by muse, mutect2, varscan2
- C1S | c.367T>C p.F123L | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61070651; called by muse, mutect2, varscan2
- CACNA1E | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.31); catalogued as rs569085430, COSV62390649; called by muse, mutect2
- CALML6 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as COSV57070278; called by muse, mutect2, varscan2
- CASS4 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV64387944; called by muse, mutect2, varscan2
- CCN4 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 51/358 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as rs766728121, COSV51534668; called by muse, mutect2, varscan2
- CCNL2 | c.519G>C p.K173N | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68766460, COSV68767034; called by muse, mutect2, varscan2
- CDCA8 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs761391083, COSV59240124; called by muse, mutect2, varscan2
- CDH20 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV53015770; called by muse, mutect2, varscan2
- CDKN2D | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.337); catalogued as COSV57265565; called by muse, mutect2
- CHST2 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV58886727; called by muse, mutect2
- CLK1 | c.354G>T p.R118S | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV58435275; called by muse, mutect2, varscan2
- CLOCK | c.1337C>G p.S446* | Nonsense Mutation (SNP) | VAF 22/359 reads (6%) | catalogued as COSV59404306; called by muse, mutect2
- COBLL1 | c.3500C>T p.S1167L (on ENST00000392717; = p.S1129L on NM_014900.5) | Missense Mutation (SNP) | VAF 142/310 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557248063, COSV52066729; called by muse, mutect2, varscan2
- CRYBA2 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV55388549; called by muse, mutect2, varscan2
- CTCFL | c.1529G>C p.G510A | Missense Mutation (SNP) | VAF 255/434 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1306940460, COSV54777746; called by muse, mutect2, varscan2
- CWC22 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 217/477 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as rs1260250909, COSV55431156, COSV55433405; called by muse, mutect2, varscan2
- CYLC1 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV61409814, COSV61410251; called by muse, mutect2, varscan2
- CYP2A6 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs1371337751, COSV56536635; called by muse, mutect2, varscan2
- DCAF6 | c.1544C>G p.S515C (on ENST00000312263 / NM_001349778.1; = p.S535C on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/423 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV56583422; called by muse, mutect2, varscan2
- DDI1 | c.939C>G p.F313L | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56389762; called by muse, mutect2, varscan2
- DDR2 | c.2507C>T p.T836M | Missense Mutation (SNP) | VAF 331/640 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as rs147604927; called by muse, mutect2, varscan2
- DEAF1 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs1357548937, COSV58608645; called by muse, mutect2
- DHX38 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51700124, COSV51700388; called by muse, mutect2, varscan2
- EIF4G3 | c.803C>G p.P268R | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as rs1298408333, COSV51690637; called by muse, mutect2, varscan2
- ELAC2 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.994); catalogued as COSV52399239; called by muse, mutect2, varscan2
- ELOF1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52948114, COSV99075650; called by muse, mutect2, varscan2
- EPHA5 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56665723; called by muse, mutect2, varscan2
- FAM135B | c.3193C>A p.P1065T | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52709656, COSV52715574, COSV52746385; called by muse, mutect2, varscan2
- FAM135B | c.713A>G p.H238R | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as rs1319344627, COSV52746405; called by muse, mutect2, varscan2
- FARS2 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as rs1167684566, COSV51173085; called by muse, mutect2, varscan2
- FAT4 | c.8997G>T p.K2999N | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.506); catalogued as COSV100627442, COSV58702343; called by muse, mutect2, varscan2
- FBXW10 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 100/568 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV57321000; called by muse, mutect2, varscan2
- FFAR3 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV59909552; called by muse, mutect2
- FIBP | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as COSV57028993; called by muse, mutect2
- FTSJ3 | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as COSV63790986; called by muse, mutect2, varscan2
- GALNT12 | c.586A>C p.K196Q | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); catalogued as COSV66663461; called by muse, mutect2, varscan2
- GC | c.975T>G p.D325E | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56739160; called by muse, mutect2, varscan2
- GEN1 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58058100; called by muse, varscan2
- GNAS | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as CD991740, COSV55684280; called by muse, mutect2
- GORASP1 | c.446T>A p.F149Y | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV56533669; called by muse, mutect2, varscan2
- GORASP1 | c.445T>G p.F149V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1389280732, COSV100072862, COSV56533672; called by muse, mutect2, varscan2
- GPR155 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55038045; called by muse, mutect2, varscan2
- GRM7 | c.2214G>A p.M738I | Missense Mutation (SNP) | VAF 98/385 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV63161836; called by muse, mutect2, varscan2
- GSTP1 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV66992777; called by muse, mutect2, varscan2
- H3C11 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.15); catalogued as COSV100137687, COSV58901117; called by muse, mutect2, varscan2
- H4C12 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100694725, COSV100694774; called by muse, mutect2, varscan2
- HABP4 | c.683G>C p.R228T | Missense Mutation (SNP) | VAF 66/391 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV64515161; called by muse, mutect2, varscan2
- HCN2 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV52113965; called by muse, mutect2, varscan2
- HCRTR2 | c.1106-2A>C p.X369_splice | Splice Site (SNP) | VAF 12/154 reads (8%) | catalogued as COSV63798308; called by muse, mutect2
- HDAC5 | c.2727+1G>A p.X909_splice | Splice Site (SNP) | VAF 29/171 reads (17%) | catalogued as COSV52243578; called by muse, mutect2, varscan2
- HGSNAT | c.1553C>G p.S518C | Missense Mutation (SNP) | VAF 709/983 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as CM071800, COSV52818449; called by muse, mutect2, varscan2
- HLA-B | c.863A>T p.E288V | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV69522661; called by muse, mutect2
- HLA-B | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 21/244 reads (9%) | catalogued as COSV69520871; called by muse, mutect2
- HLTF | c.2495G>A p.S832N | Missense Mutation (SNP) | VAF 126/1000 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs554839264, COSV59502857; called by muse, mutect2, varscan2
- HOMER1 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 66/394 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1346817873, COSV56529361; called by muse, mutect2, varscan2
- HYDIN | c.9852C>A p.N3284K | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV66872699, COSV66877911; called by muse, mutect2, varscan2
- HYDIN | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165200989, COSV55489076, COSV55495639; called by mutect2, varscan2
- IFRD1 | c.1148C>G p.S383* | Nonsense Mutation (SNP) | VAF 56/372 reads (15%) | catalogued as COSV50044938; called by muse, mutect2, varscan2
- ITGAM | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54940982; called by muse, mutect2
- JAKMIP3 | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV53827867; called by muse, mutect2
- JMJD7-PLA2G4B | c.2888C>A p.S963Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58026186; called by muse, mutect2, varscan2
- JMY | c.1635G>C p.L545F | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV68661987; called by muse, mutect2
- KAT6A | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 180/526 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.036); catalogued as COSV55910779; called by muse, mutect2, varscan2
- KAT6A | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 165/445 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV55910784; called by muse, mutect2, varscan2
- KCNMA1 | c.1057G>T p.V353F | Missense Mutation (SNP) | VAF 53/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54234358, COSV54275501; called by muse, mutect2, varscan2
- KCNS2 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 61/320 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54640285; called by muse, mutect2, varscan2
- KDM5B | c.4235G>C p.R1412T | Missense Mutation (SNP) | VAF 110/287 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV52511397; called by muse, mutect2, varscan2
- KEL | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs373423972; called by muse, mutect2, varscan2
- KHDRBS1 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 45/292 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.374); catalogued as COSV56983288; called by muse, mutect2, varscan2
- KIT | c.2596+2T>G p.X866_splice | Splice Site (SNP) | VAF 18/550 reads (3%) | catalogued as rs1348315872, COSV55415715; called by muse, mutect2
- KIZ | c.785A>G p.K262R | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV55687406; called by muse, mutect2
- KLHL13 | c.375T>A p.G125= | Splice Region (SNP) | VAF 26/106 reads (25%) | catalogued as COSV53251747; called by muse, mutect2, varscan2
- KPNA6 | c.1537C>A p.P513T | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV65361693; called by muse, mutect2, varscan2
- KRT27 | c.127A>T p.S43C | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV56972981; called by muse, mutect2, varscan2
- KTN1 | c.1861G>T p.D621Y | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68025079; called by muse, mutect2, varscan2
- LCTL | c.1216C>G p.P406A | Missense Mutation (SNP) | VAF 41/349 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV57181510, COSV57182240; called by muse, mutect2, varscan2
- LGALS9 | c.731C>G p.S244* (on ENST00000395473 / NM_009587.3; = p.S212* on NM_002308.4) | Nonsense Mutation (SNP) | VAF 19/298 reads (6%) | catalogued as COSV56350557; called by muse, mutect2
- LPAR2 | c.587C>G p.S196W | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV52559077; called by muse, mutect2
- LPO | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51858594, COSV51861629; called by muse, mutect2, varscan2
- LRAT | c.237G>T p.L79F | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as COSV60477864; called by muse, mutect2, varscan2
- MAGEB6 | c.1130C>A p.A377D | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66872504, COSV66872841; called by muse, mutect2, varscan2
- MAP3K19 | c.3823G>A p.A1275T | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340999989, COSV59641348; called by muse, mutect2, varscan2
- MAPK8 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 69/378 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64409012, COSV64410631; called by muse, mutect2, varscan2
- MASTL | c.1141A>C p.T381P | Missense Mutation (SNP) | VAF 57/308 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs756835266, COSV60912139; called by muse, mutect2, varscan2
- MATR3 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 48/338 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.375); catalogued as COSV63079113; called by muse, mutect2, varscan2
- MCM9 | c.233T>G p.L78W | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV60165076; called by muse, mutect2
- MGA | c.3313C>T p.H1105Y | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV54960749; called by muse, mutect2, varscan2
- MINDY1 | c.1330-1G>A p.X444_splice | Splice Site (SNP) | VAF 16/86 reads (19%) | catalogued as COSV56500378; called by muse, mutect2, varscan2
- MOAP1 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.479); catalogued as rs1054335497, COSV52093252; called by muse, mutect2, varscan2
- MOCOS | c.1498C>G p.Q500E | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54341053; called by muse, mutect2, varscan2
- MORC3 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as COSV68689010; called by muse, mutect2, varscan2
- MRPS18B | c.346G>C p.D116H | Missense Mutation (SNP) | VAF 53/450 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); catalogued as COSV52542345; called by muse, mutect2, varscan2
- MRPS23 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 109/906 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58032792; called by muse, mutect2, varscan2
- MUC16 | c.35425G>C p.E11809Q | Missense Mutation (SNP) | VAF 35/400 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV67484560; called by muse, mutect2
- MUC16 | c.1482T>A p.S494R | Missense Mutation (SNP) | VAF 309/539 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); catalogued as COSV101202299, COSV67484566; called by muse, mutect2, varscan2
- MUC5B | c.14810C>G p.S4937C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.352); catalogued as COSV71594610; called by muse, mutect2, varscan2
- MX1 | c.1911C>G p.S637R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.061); catalogued as COSV55820479; called by muse, mutect2, varscan2
- MYH13 | c.3252G>C p.L1084F | Missense Mutation (SNP) | VAF 70/414 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV52833009, COSV52838817; called by muse, mutect2
- MYLIP | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.639); catalogued as COSV62767441; called by muse, mutect2, varscan2
- NAGPA | c.1301A>C p.E434A | Missense Mutation (SNP) | VAF 18/111 reads (16%) | PolyPhen benign (0); catalogued as COSV56570650; called by muse, mutect2, varscan2
- NEK10 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 24/463 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs916986757, COSV58288063; called by muse, mutect2
- NFKBIA | c.261G>C p.K87N | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.868); catalogued as COSV53754242; called by muse, mutect2, varscan2
- NIN | c.4549G>A p.E1517K (on ENST00000382041 / NM_182946.1; = p.E804K on NM_016350.4) | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV55402377; called by muse, mutect2, varscan2
- NOMO3 | c.2306C>G p.S769C | Missense Mutation (SNP) | VAF 20/618 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53770404; called by muse, mutect2
- NPFFR1 | c.162C>A p.F54L | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV53334429; called by muse, mutect2, varscan2
- NRAP | c.4790G>A p.R1597Q (on ENST00000359988 / NM_001322945.2; = p.R1562Q on NM_006175.4) | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as rs774253209, COSV63493154; called by muse, mutect2, varscan2
- NTM | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV66189641; called by muse, mutect2, varscan2
- NUP205 | c.2968C>G p.L990V | Missense Mutation (SNP) | VAF 60/656 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as rs761560315, COSV53664341; called by muse, mutect2
- OPA1 | c.2920G>A p.E974K (on ENST00000361510 / NM_130837.3; = p.E919K on NM_015560.3) | Missense Mutation (SNP) | VAF 58/769 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV62482686; called by muse, mutect2
- OR5W2 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60617867; called by muse, mutect2, varscan2
- OR6C3 | c.685A>C p.S229R | Missense Mutation (SNP) | VAF 97/646 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV65571717; called by muse, mutect2, varscan2
- PACRG | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 34/214 reads (16%) | catalogued as rs369094995; called by muse, mutect2, varscan2
- PAPPA | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV60289799, COSV60290960; called by mutect2, varscan2
- PAX8 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs749062101, COSV54511359; called by muse, mutect2, varscan2
- PCSK9 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as rs749049179, COSV56163984; called by muse, mutect2, varscan2
- PDE6A | c.2226C>G p.F742L | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54930444; called by muse, mutect2, varscan2
- PDZRN4 | c.958G>T p.A320S (on ENST00000402685 / NM_001164595.2; = p.A62S on NM_013377.4) | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV54212572; called by muse, mutect2, varscan2
- PEPD | c.651G>C p.M217I | Missense Mutation (SNP) | VAF 108/732 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV54894632; called by muse, mutect2, varscan2
- PIGN | c.1468G>C p.A490P | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV62951238; called by muse, mutect2, varscan2
- PKD2L2 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51800377; called by muse, mutect2, varscan2
- PKHD1L1 | c.3202C>G p.L1068V | Missense Mutation (SNP) | VAF 73/424 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65750120; called by muse, mutect2, varscan2
- POLQ | c.2072A>C p.E691A | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV51758922; called by muse, mutect2, varscan2
- POMT2 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1391641457, COSV55072965; called by muse, mutect2, varscan2
- POU6F2 | c.965G>C p.G322A | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.996); catalogued as COSV68880075; called by muse, mutect2, varscan2
- PRDM9 | c.1364A>G p.E455G | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV57011246; called by muse, mutect2, varscan2
- PROK1 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.253); catalogued as COSV54765471; called by muse, mutect2, varscan2
- PSD | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); catalogued as COSV50054672; called by muse, mutect2, varscan2
- PSMA8 | c.300G>C p.Q100H | Missense Mutation (SNP) | VAF 24/516 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57604425; called by muse, mutect2
- PSMB6 | c.416C>G p.P139R | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV54513290; called by muse, mutect2, varscan2
- PTCHD3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71256863, COSV71257204; called by muse, mutect2, varscan2
- RAC2 | c.105C>T p.T35= | Splice Region (SNP) | VAF 68/362 reads (19%) | catalogued as rs760366847, COSV50775124; called by muse, mutect2
- RASGRF1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1278280678, COSV69177841; called by muse, mutect2, varscan2
- RASGRF2 | c.1930G>A p.V644M | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs774520224, COSV54136830; called by muse, mutect2, varscan2
- RNFT1 | c.682C>A p.L228I | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59870345; called by muse, mutect2, varscan2
- RNPEPL1 | c.1462C>G p.L488V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV54373589; called by muse, mutect2, varscan2
- ROBO1 | c.4009G>T p.E1337* | Nonsense Mutation (SNP) | VAF 21/169 reads (12%) | catalogued as COSV71397442; called by muse, mutect2, varscan2
- ROBO1 | c.4008G>T p.M1336I | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV71397443; called by muse, mutect2, varscan2
- RTL8C | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV57060416; called by muse, mutect2, varscan2
- SCN7A | c.2700T>A p.G900= | Splice Region (SNP) | VAF 38/233 reads (16%) | catalogued as COSV69273364, COSV69273890; called by muse, mutect2, varscan2
- SEC14L5 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1005454231, COSV52038272, COSV52040957; called by mutect2, varscan2
- SEPTIN5 | c.1071G>C p.E357D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV63530938; called by muse, mutect2, varscan2
- SH3GL3 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as rs369784464, COSV61060314; called by muse, mutect2, varscan2
- SLC39A11 | c.659A>G p.E220G (on ENST00000542342 / NM_001159770.2; = p.E213G on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55298822; called by muse, mutect2, varscan2
- SLCO1A2 | c.1462C>G p.Q488E | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56598681, COSV56608398; called by muse, mutect2, varscan2
- SMG6 | c.2180G>T p.R727L | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53973314; called by muse, mutect2, varscan2
- SPANXN2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 86/431 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV65129165; called by muse, varscan2
- STING1 | c.827A>C p.Q276P | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.093); catalogued as COSV58173308; called by muse, mutect2, varscan2
- STK16 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759279513, COSV50280618; called by muse, mutect2, varscan2
- STXBP3 | c.50-1G>C p.X17_splice | Splice Site (SNP) | VAF 66/365 reads (18%) | catalogued as COSV64181448, COSV64183276; called by muse, mutect2, varscan2
- SUCNR1 | c.734T>C p.F245S | Missense Mutation (SNP) | VAF 94/621 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62912681; called by muse, mutect2, varscan2
- TAAR6 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV51584614, COSV51585065; called by muse, mutect2, varscan2
- TAF3 | c.1777A>T p.K593* | Nonsense Mutation (SNP) | VAF 61/116 reads (53%) | catalogued as COSV60210228; called by muse, mutect2, varscan2
- TARBP1 | c.1181A>G p.E394G | Missense Mutation (SNP) | VAF 352/772 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50199303; called by muse, mutect2, varscan2
- TARDBP | c.962C>G p.A321G | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as rs1304706298, CM097288, CM104429, COSV53569167, COSV53570978; called by muse, mutect2, varscan2
- TAS2R20 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV101114955, COSV67861197; called by muse, mutect2, varscan2
- TCERG1L | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100894273, COSV64055106; called by muse, mutect2, varscan2
- TENM3 | c.3100G>T p.V1034F | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101305620, COSV69315949; called by muse, mutect2, varscan2
- TIGD7 | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 57/363 reads (16%) | catalogued as COSV51916708; called by muse, mutect2, varscan2
- TMEM81 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 139/346 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV52706292; called by muse, mutect2, varscan2
- TNIK | c.1611A>G p.V537= | Splice Region (SNP) | VAF 16/188 reads (9%) | catalogued as rs1403732161, COSV52692018; called by muse, mutect2
- TNKS2 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 57/357 reads (16%) | catalogued as rs372595864; called by muse, mutect2, varscan2
- TNNT3 | c.462G>T p.K154N (on ENST00000397301 / NM_001367846.1; = p.K143N on NM_006757.4) | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53488825; called by muse, mutect2, varscan2
- TRIR | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 38/573 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); catalogued as COSV54406468; called by muse, mutect2
- TTC27 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 73/480 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV58655603; called by muse, mutect2, varscan2
- TXNRD1 | c.1609G>C p.E537Q (on ENST00000525566 / NM_001093771.3; = p.E439Q on NM_003330.4) | Missense Mutation (SNP) | VAF 45/313 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61597226, COSV61600272; called by muse, mutect2, varscan2
- UBR2 | c.1172G>C p.R391P | Missense Mutation (SNP) | VAF 165/470 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as COSV100867355, COSV65751914; called by muse, mutect2, varscan2
- UGT3A2 | c.1272G>A p.M424I | Missense Mutation (SNP) | VAF 60/364 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.755); catalogued as COSV56932658; called by muse, mutect2, varscan2
- UNC79 | c.1345G>A p.V449M (on ENST00000393151 / NM_001346218.2; = p.V272M on NM_020818.5) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1202328958, COSV56404514; called by muse, mutect2
- USP10 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54749211; called by muse, mutect2, varscan2
- VPS8 | c.2308G>C p.E770Q (on ENST00000625842 / NM_001349294.1; = p.E768Q on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/439 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.193); catalogued as COSV54993801; called by muse, mutect2, varscan2
- XRN1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.644); catalogued as COSV53816482; called by muse, mutect2, varscan2
- YPEL2 | c.97C>G p.H33D | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV57073248; called by muse, mutect2, varscan2
- ZAN | c.5421C>G p.F1807L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.747); catalogued as COSV61813914; called by muse, mutect2
- ZFHX4 | c.7378G>A p.G2460R | Missense Mutation (SNP) | VAF 55/397 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.07); catalogued as rs984136010, COSV50657337; called by muse, mutect2, varscan2
- ZFPM2 | c.3373G>C p.D1125H | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65875311; called by muse, mutect2, varscan2
- ZFYVE16 | c.3370G>A p.D1124N | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.285); catalogued as COSV62017033; called by muse, mutect2, varscan2
- ZHX2 | c.599C>G p.P200R | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV58715924; called by muse, mutect2, varscan2
- ZMYM2 | c.4123G>C p.D1375H | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67036769; called by muse, mutect2, varscan2
- ZNF337 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 146/314 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV53322704; called by muse, mutect2, varscan2
- ZNF570 | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV57580064, COSV57580335; called by muse, mutect2, varscan2
- ZNF749 | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61947708; called by muse, mutect2, varscan2
- ZNF770 | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 39/480 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1418306513, COSV62544777; called by muse, mutect2
- MFSD14B | c.1485_1496del p.F496_P499del | In Frame Del (DEL) | VAF 35/119 reads (29%) | called by mutect2, pindel, varscan2
- MYO3A | c.3574del p.M1192* | Frame Shift Del (DEL) | VAF 24/164 reads (15%) | called by mutect2, varscan2
- SPON2 | c.718A>C p.T240P | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); called by muse, mutect2
- ADAMTS3 | c.129G>A p.E43= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as rs752668617, COSV54395710, COSV54399266; called by muse, mutect2, varscan2
- AKAP7 | c.396G>A p.V132= | Silent (SNP) | VAF 30/345 reads (9%) | catalogued as COSV63505619; called by muse, mutect2
- ASXL3 | c.3360C>T p.L1120= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV52475653; called by muse, mutect2, varscan2
- ATP1A2 | c.1815C>T p.S605= | Silent (SNP) | VAF 62/240 reads (26%) | catalogued as rs771651622, COSV63404291; ClinVar: likely benign; called by muse, mutect2, varscan2
- CELSR1 | c.3993C>T p.L1331= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as rs1458995662, COSV53092718, COSV53097285; called by muse, mutect2, varscan2
- CLASP1 | c.1698G>A p.P566= | Silent (SNP) | VAF 25/158 reads (16%) | catalogued as rs372220696; called by muse, mutect2, varscan2
- CSMD3 | c.2589A>T p.G863= (on ENST00000297405 / NM_001363185.1; = p.G759= on NM_052900.3) | Silent (SNP) | VAF 31/268 reads (12%) | catalogued as COSV52280517; called by muse, mutect2, varscan2
- DENND3 | c.204C>T p.T68= | Silent (SNP) | VAF 31/232 reads (13%) | catalogued as rs371746143, COSV99371087; called by muse, mutect2, varscan2
- EPB41L3 | c.3039C>T p.T1013= | Silent (SNP) | VAF 40/470 reads (9%) | catalogued as COSV59464397; called by muse, mutect2
- EXOC4 | c.2463C>T p.I821= | Silent (SNP) | VAF 30/267 reads (11%) | catalogued as COSV54115459; called by muse, mutect2, varscan2
- HDLBP | c.2985C>T p.I995= | Silent (SNP) | VAF 40/221 reads (18%) | catalogued as COSV60499660; called by muse, mutect2, varscan2
- HMOX1 | c.183G>A p.L61= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV53340918; called by muse, mutect2, varscan2
- HTR3C | c.729C>T p.I243= | Silent (SNP) | VAF 30/289 reads (10%) | catalogued as COSV59176704; called by muse, mutect2
- IFNA5 | c.141C>T p.I47= | Silent (SNP) | VAF 39/192 reads (20%) | catalogued as COSV52387388; called by muse, mutect2, varscan2
- MAMDC2 | c.705C>T p.I235= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV65857333; called by muse, mutect2, varscan2
- MCM3AP | c.1023G>T p.T341= | Silent (SNP) | VAF 29/165 reads (18%) | catalogued as rs1160997029, COSV52444137; called by muse, mutect2, varscan2
- MYCBP2 | c.9273G>A p.L3091= (on ENST00000357337; = p.L3129= on NM_015057.5) | Silent (SNP) | VAF 27/200 reads (14%) | catalogued as COSV62034111; called by mutect2, varscan2
- OR52D1 | c.282G>A p.E94= | Silent (SNP) | VAF 42/264 reads (16%) | catalogued as rs370177548, COSV59488139; called by muse, mutect2, varscan2
- OR52K1 | c.189C>G p.L63= | Silent (SNP) | VAF 69/341 reads (20%) | catalogued as COSV56904461; called by muse, mutect2, varscan2
- OR5AC2 | c.141G>A p.L47= | Silent (SNP) | VAF 100/605 reads (17%) | catalogued as COSV62279996; called by muse, mutect2, varscan2
- P2RY8 | c.843C>G p.L281= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV67178018; called by muse, mutect2, varscan2
- PCDHGC3 | c.357C>T p.F119= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as rs747179611, COSV52763150; called by muse, mutect2, varscan2
- PLCH1 | c.4524G>A p.E1508= (on ENST00000340059 / NM_001130960.2; = p.E1500= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/317 reads (20%) | catalogued as COSV58207506; called by muse, mutect2, varscan2
- PLIN4 | c.2427C>T p.T809= (on ENST00000301286; = p.T824= on NM_001367868.2) | Silent (SNP) | VAF 41/246 reads (17%) | catalogued as rs745340814; called by muse, mutect2, varscan2
- POU3F3 | c.1089C>T p.F363= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV63721215; called by muse, mutect2, varscan2
- QRICH1 | c.1650T>C p.Y550= | Silent (SNP) | VAF 47/249 reads (19%) | catalogued as COSV62617255; called by muse, mutect2, varscan2
- RASSF8 | c.1056C>T p.F352= | Silent (SNP) | VAF 46/246 reads (19%) | catalogued as COSV51454919; called by muse, mutect2, varscan2
- RYR2 | c.8758C>A p.R2920= | Silent (SNP) | VAF 29/410 reads (7%) | catalogued as rs767451825, COSV63705846; called by muse, mutect2
- SCN9A | c.3006G>T p.V1002= (on ENST00000303354; = p.V991= on NM_002977.3) | Silent (SNP) | VAF 32/252 reads (13%) | catalogued as COSV57620286; called by muse, varscan2
- SEC23IP | c.720G>A p.P240= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as rs373510596, COSV64830999; called by muse, mutect2, varscan2
- SEC24A | c.1326C>G p.V442= | Silent (SNP) | VAF 120/391 reads (31%) | catalogued as COSV59749121; called by muse, mutect2, varscan2
- SERPINA7 | c.576C>G p.L192= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as COSV100568162, COSV59666978; called by muse, mutect2, varscan2
- SI | c.5370C>T p.N1790= | Silent (SNP) | VAF 130/730 reads (18%) | catalogued as rs760411938, COSV52291316; called by muse, mutect2, varscan2
- SLC16A14 | c.558C>T p.Y186= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs201216147, COSV54620620; called by muse, mutect2, varscan2
- SLC29A3 | c.21C>T p.D7= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs746298917, COSV64385899; called by muse, mutect2, varscan2
- SNX1 | c.648C>T p.L216= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs763805528, COSV56039510; called by muse, mutect2, varscan2
- SVEP1 | c.4383C>T p.D1461= | Silent (SNP) | VAF 48/269 reads (18%) | catalogued as rs368920627; called by muse, mutect2, varscan2
- TLE3 | c.828C>T p.A276= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as rs1286152595, COSV58173298; called by muse, mutect2, varscan2
- TM2D3 | c.696C>G p.L232= (on ENST00000333202 / NM_078474.3; = p.L206= on NM_025141.3) | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV60881707; called by muse, mutect2, varscan2
- TTN | c.87462C>A p.V29154= (on ENST00000591111; = p.V21730= on NM_003319.4) | Silent (SNP) | VAF 49/346 reads (14%) | catalogued as rs376597397, COSV100633642; ClinVar: likely benign; called by muse, mutect2, varscan2
- WAPL | c.798C>T p.D266= | Silent (SNP) | VAF 29/195 reads (15%) | catalogued as rs777078143, COSV53938906; called by muse, mutect2, varscan2
- ZBTB10 | c.447C>T p.P149= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV66948357; called by muse, mutect2
- ZCCHC4 | c.852A>G p.E284= | Silent (SNP) | VAF 53/318 reads (17%) | catalogued as rs758186304, COSV57182969; called by muse, mutect2, varscan2
- ZNF425 | c.987C>T p.P329= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs1371582468, COSV65202255; called by muse, mutect2, varscan2
- ZSCAN5A | c.606A>G p.L202= | Silent (SNP) | VAF 68/715 reads (10%) | catalogued as COSV54227176; called by muse, mutect2
- ZXDA | c.1932C>A p.L644= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100699405; called by mutect2, varscan2
